Somatic mutation profile of tumor specimen MBCProject_0203_T1C_WES (aliquot MBCProject_0203_T1C_WES_1) from CMI case MBCProject_0203, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.4 years (17,691 days).
Specimen MBCProject_0203_T1C_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d68e6b79-88cd-4723-b732-c5afbd6415f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0203_SALIVA (Saliva), aliquot MBCProject_0203_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e77df8-118c-49a1-a9a7-6a00b77e77b3

The open-access MAF lists 119 somatic variants for this specimen: 88 protein-altering or splice-affecting, 16 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 16, Intron 9, Frame Shift Del 5, In Frame Del 5, Splice Site 3, Nonsense Mutation 2, 3'UTR 2, 5'UTR 2, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3227T>A p.I1076K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1356591712, COSV99684907; called by mutect2, varscan2
- AMER1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV57658675; called by mutect2, varscan2
- AOC3 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs151291423; called by muse, mutect2, varscan2
- ASTN1 | c.3807C>G p.S1269R | Missense Mutation (SNP) | VAF 108/406 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100706916; called by muse, mutect2, varscan2
- CBY2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV60118086; called by muse, mutect2, varscan2
- CHERP | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs779384365, COSV52226935; called by muse, mutect2, varscan2
- CHST2 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs769639046; called by muse, varscan2
- DNAI4 | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755382003; called by muse, mutect2, varscan2
- DOC2A | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58751371; called by muse, mutect2, varscan2
- FAM20C | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as rs1245703345; called by muse, mutect2, varscan2
- HUWE1 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53339081; called by mutect2, varscan2
- MAP4K1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs770505238; called by muse, mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, varscan2
- NR6A1 | c.563A>T p.N188I (on ENST00000487099 / NM_033334.4; = p.N184I on NM_001489.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV60633434; called by muse, mutect2, varscan2
- OR14A2 | c.728del p.L243Pfs*9 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as COSV100825424; called by mutect2, pindel
- OR7A10 | c.533dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | catalogued as rs758596389; called by mutect2, pindel, varscan2
- PLEKHG4B | c.3383T>G p.F1128C (on ENST00000283426; = p.F1484C on NM_052909.5) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52054960; called by muse, mutect2, varscan2
- POU6F2 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1472321299; called by muse, mutect2
- PRR30 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1382257449; called by muse, mutect2, varscan2
- SELENOV | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1462075637; called by muse, mutect2
- SPG7 | c.1903G>A p.E635K (on ENST00000268704; = p.E642K on NM_003119.4) | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202120338, COSV51954483; called by muse, mutect2, varscan2
- TCP10L | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746268293; called by muse, varscan2
- TGM2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs577909675; called by muse, mutect2, varscan2
- ABCC12 | c.3715-17_3744del p.X1239_splice | Splice Site (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ANK3 | c.6587C>A p.P2196H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO4 | c.2589C>A p.D863E (on ENST00000392977 / NM_001286615.2; = p.D828E on NM_178826.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, varscan2
- ARHGAP42 | c.755G>T p.R252M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- ARHGEF11 | c.2779A>T p.T927S | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- ATP2B4 | c.148_162delinsCTA p.G50_N53del | In Frame Del (DEL) | VAF 22/93 reads (24%) | called by pindel, varscan2*
- CALCR | c.588G>T p.R196S (on ENST00000649521 / NM_001164737.2; = p.R180S on NM_001742.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDYL | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- COL16A1 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX31 | c.2372A>G p.Y791C | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DNAH3 | c.4662G>A p.M1554I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by mutect2, varscan2
- DNAJC18 | c.312_324del p.K104Nfs*19 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- DOK5 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- EMC1 | c.1038C>G p.S346R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EMILIN1 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by mutect2, varscan2
- EPS8L2 | c.984+2T>C p.X328_splice | Splice Site (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- FAM122A | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FBXO41 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSD1 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FUZ | c.371_372insTTT p.L124dup | In Frame Ins (INS) | VAF 29/287 reads (10%) | called by mutect2, pindel
- GCM2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 140/653 reads (21%) | called by muse, mutect2, varscan2
- GH1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRIN1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GRK2 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- HTR3A | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQCF1 | c.171+1_171+6del p.X57_splice | Splice Site (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- IQCF5 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6B | c.4901del p.F1634Sfs*36 (on ENST00000448097 / NM_001348716.1; = p.F1634Sfs*4 on NM_001080424.2) | Frame Shift Del (DEL) | VAF 55/311 reads (18%) | called by mutect2, pindel, varscan2
- KIAA0895 | c.1028A>G p.N343S (on ENST00000297063 / NM_001100425.2; = p.N292S on NM_015314.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KIAA1109 | c.8012A>G p.K2671R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA1549L | c.3911C>T p.P1304L (on ENST00000321505; = p.P1601L on NM_012194.3) | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF1A | c.4459A>T p.S1487C (on ENST00000320389 / NM_001379639.1; = p.S1479C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAOA | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP1A | c.7006_7017del p.H2336_C2339del | In Frame Del (DEL) | VAF 22/168 reads (13%) | called by mutect2, pindel
- MAPKBP1 | c.1337A>G p.D446G (on ENST00000456763 / NM_001128608.2; = p.D440G on NM_014994.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- MLLT6 | c.2975_3013del p.P992_L1004del | In Frame Del (DEL) | VAF 20/144 reads (14%) | called by mutect2, pindel
- MRPL17 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MUC16 | c.34895C>A p.T11632N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.3359_3376del p.I1120_T1125del | In Frame Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- MYH7 | c.1074C>A p.H358Q | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MYT1L | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- OXCT1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OXCT1 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.1208_1210del p.Q403del | In Frame Del (DEL) | VAF 30/227 reads (13%) | called by pindel, varscan2
- PLCG2 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2
- PSG4 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PTPRM | c.4294G>T p.V1432F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RABGAP1L | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- RPGR | c.2857A>G p.I953V (on ENST00000339363 / NM_001367249.1; = p.I748V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA6 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC1A4 | c.329T>A p.L110H | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC22A31 | c.237del p.D81Tfs*13 | Frame Shift Del (DEL) | VAF 34/199 reads (17%) | called by pindel, varscan2
- SLC35A1 | c.988T>G p.S330A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLCO5A1 | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SNIP1 | c.1097_1116del p.E366Vfs*6 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel
- SPRYD3 | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- STAB2 | c.3518C>T p.T1173I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TAF1L | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ZAN | c.3725C>G p.A1242G | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.423); called by muse, varscan2
- ZIC4 | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF217 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF235 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZSCAN1 | c.757A>T p.R253W | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ZSCAN22 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.906C>T p.I302= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- CACNA1B | c.1695C>A p.A565= | Silent (SNP) | VAF 75/225 reads (33%) | called by muse, mutect2, varscan2
- COL20A1 | c.1293G>A p.T431= | Silent (SNP) | VAF 166/477 reads (35%) | catalogued as rs780583500, COSV58918554; called by muse, mutect2, varscan2
- ERCC1 | c.483G>A p.G161= | Silent (SNP) | VAF 54/423 reads (13%) | catalogued as rs371397437; called by muse, mutect2, varscan2
- GAL3ST3 | c.924C>T p.H308= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs1222376422; called by muse, mutect2, varscan2
- ITGA9 | c.519C>T p.G173= | Silent (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- KCND3 | c.1749G>A p.Q583= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- KLHDC8A | c.727C>A p.R243= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- MAP4K4 | c.516T>C p.F172= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs1268907751; called by muse, mutect2, varscan2
- MUC1 | c.3705C>G p.P1235= (on ENST00000611571 / NM_001371720.1; = p.P246= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- MUC5B | c.828A>T p.A276= | Silent (SNP) | VAF 46/508 reads (9%) | called by muse, mutect2
- P3H3 | c.81G>A p.Q27= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2
- PDE4DIP | c.3024C>T p.H1008= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.1422G>A p.L474= | Silent (SNP) | VAF 31/347 reads (9%) | catalogued as COSV51933771, COSV99240493; called by muse, mutect2
- RASGRP4 | c.645G>C p.R215= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- TRAV6 | c.309C>G p.V103= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701643 A>T | 3'Flank (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- BUD31 | c.94+568C>G | Intron (SNP) | VAF 11/123 reads (9%) | called by muse, varscan2
- CFTR | c.-34C>T | 5'UTR (SNP) | VAF 42/196 reads (21%) | catalogued as rs756314710, CR118489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRIM1 | c.2429-5437C>T | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*1799A>G | 3'UTR (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
- LTB | c.208+43G>C | Intron (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- NECAP2 | c.489+959C>G | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54896C>A | Intron (SNP) | VAF 14/88 reads (16%) | catalogued as rs1374824140; called by muse, mutect2, varscan2
- POLR2H | c.-53C>G | 5'UTR (SNP) | VAF 141/486 reads (29%) | called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs1356395055; called by muse, varscan2
- SNX29 | c.247+2193T>G | Intron (SNP) | VAF 16/140 reads (11%) | called by muse, varscan2
- STXBP2 | c.88-22_88-19del | Intron (DEL) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- TK1 | chr17:78187097 A>G | 5'Flank (SNP) | VAF 20/298 reads (7%) | catalogued as rs1216718360; called by muse, mutect2
- UMPS | c.*377A>C | 3'UTR (SNP) | VAF 8/77 reads (10%) | catalogued as rs927558442; called by muse, mutect2
- ZNF695 | c.259+3213T>G | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as rs1167521789; called by mutect2, varscan2
